Somatic mutation profile of tumor specimen TCGA-GN-A4U5-01A (aliquot TCGA-GN-A4U5-01A-11D-A32N-08) from TCGA case TCGA-GN-A4U5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 61.6 years (22,499 days).
Specimen TCGA-GN-A4U5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ebcba44-5edb-4ba2-b927-07d7db3168eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A4U5-10B (Blood Derived Normal), aliquot TCGA-GN-A4U5-10B-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d773a75-ba87-49c2-aa70-6828723856c0

The open-access MAF lists 390 somatic variants for this specimen: 256 protein-altering or splice-affecting, 123 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 233, Silent 123, Nonsense Mutation 16, Splice Site 4, RNA 4, Intron 4, 3'UTR 2, Frame Shift Ins 1, In Frame Ins 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 65/265 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADAC | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as rs964630138, COSV99233520; called by muse, mutect2, varscan2
- ABCA4 | c.4940G>A p.R1647K | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100933270; called by muse, mutect2, varscan2
- ABCG2 | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV52948841; called by muse, mutect2, varscan2
- ACAD10 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 87/318 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100564646; called by muse, mutect2, varscan2
- ACAT2 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100887197; called by muse, mutect2, varscan2
- ACSM2A | c.177G>T p.K59N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV99525755; called by muse, mutect2, varscan2
- ACY3 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761509817, COSV99663171; called by muse, mutect2, varscan2
- ADAMTSL2 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.138); catalogued as COSV100619052; called by muse, mutect2, varscan2
- ADCK2 | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 38/169 reads (22%) | catalogued as COSV99301883; called by muse, mutect2, varscan2
- AMMECR1 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV99467214; called by muse, mutect2, varscan2
- ANKH | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99414879; called by muse, mutect2, varscan2
- APBB1IP | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV100881997; called by muse, mutect2, varscan2
- ARHGAP28 | c.764C>T p.S255F (on ENST00000383472 / NM_001366230.1; = p.S96F on NM_001010000.3) | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.388); catalogued as COSV51643275, COSV99151468; called by muse, mutect2, varscan2
- ASIC1 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as rs989125476, COSV57318932; called by muse, mutect2, varscan2
- ASTN2 | c.1943C>T p.S648F (on ENST00000313400 / NM_001365069.1; = p.S597F on NM_014010.5) | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57812740, COSV57817008; called by muse, mutect2, varscan2
- BRINP3 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 69/344 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs866742953, COSV66521468; called by muse, mutect2, varscan2
- C12orf60 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99966997; called by muse, mutect2, varscan2
- C6 | c.2659C>G p.Q887E | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as COSV54715694; called by muse, mutect2, varscan2
- C6 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs267600638, COSV54704649; called by muse, mutect2, varscan2
- C7 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV57481875; called by muse, mutect2, varscan2
- CASK | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); catalogued as COSV100587814; called by muse, varscan2
- CCDC102A | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as COSV99265247; called by muse, mutect2, varscan2
- CCDC137 | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100235834, COSV61304017; called by muse, mutect2, varscan2
- CCDC158 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.393); catalogued as COSV101187388, COSV66355487; called by muse, mutect2, varscan2
- CD4 | c.731G>A p.R244K | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50589411; called by muse, mutect2, varscan2
- CD96 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV51913310; called by muse, mutect2, varscan2
- CDH26 | c.2459C>T p.P820L (on ENST00000348616 / NM_177980.4; = p.P153L on NM_021810.6) | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs773831785, COSV99721775, COSV99722858; called by muse, mutect2, varscan2
- CELSR1 | c.8650G>A p.V2884M | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV99420138; called by muse, mutect2, varscan2
- CEMIP | c.3166C>T p.H1056Y | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99587331; called by muse, mutect2, varscan2
- CERKL | c.1159G>A p.D387N (on ENST00000339098 / NM_001030311.2; = p.D361N on NM_201548.5) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100184216; called by muse, mutect2, varscan2
- CFHR5 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56820648; called by muse, mutect2, varscan2
- CLCA1 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99322892; called by muse, mutect2, varscan2
- CLCN4 | c.2042C>T p.P681L | Missense Mutation (SNP) | VAF 56/292 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.714); catalogued as COSV101074085; called by muse, mutect2, varscan2
- CLGN | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV100346838; called by muse, mutect2, varscan2
- CLIP2 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99792355; called by muse, mutect2, varscan2
- CNTN5 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.984); catalogued as COSV99681570; called by muse, mutect2, varscan2
- CNTNAP2 | c.1349-2A>G p.X450_splice | Splice Site (SNP) | VAF 59/165 reads (36%) | catalogued as rs1433216677, COSV100673282; called by muse, mutect2, varscan2
- CNTNAP3 | c.2476T>A p.S826T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.06); catalogued as COSV99905684; called by muse, mutect2, varscan2
- COBL | c.2053C>T p.P685S | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as COSV99474300; called by muse, mutect2, varscan2
- COL4A5 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 48/271 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100090052; called by muse, mutect2, varscan2
- COLEC10 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60520707; called by muse, mutect2, varscan2
- COX7C | c.104G>A p.W35* | Nonsense Mutation (SNP) | VAF 33/173 reads (19%) | catalogued as COSV99915255; called by muse, mutect2, varscan2
- CRACDL | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101194155; called by muse, mutect2, varscan2
- CREBRF | c.494A>G p.Q165R | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.136); catalogued as COSV99756454; called by muse, mutect2, varscan2
- CSMD3 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV52225581; called by muse, mutect2, varscan2
- CSTL1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs747678678, COSV55677990; called by muse, mutect2, varscan2
- CTNNA3 | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV101051730; called by muse, mutect2
- CXCR1 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.222); catalogued as rs1240309119, COSV99826441; called by muse, mutect2, varscan2
- CYP4A11 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as rs536828497, COSV100152646; called by muse, mutect2, varscan2
- CYP4F3 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV55407005; called by muse, mutect2, varscan2
- DAP3 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100546624; called by muse, mutect2, varscan2
- DAP3 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100546673; called by muse, mutect2, varscan2
- DCDC1 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.177); catalogued as COSV60834244; called by muse, mutect2, varscan2
- DCLK3 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV101374147; called by muse, mutect2, varscan2
- DDX4 | c.18G>A p.W6* | Nonsense Mutation (SNP) | VAF 32/115 reads (28%) | catalogued as COSV100737799; called by muse, mutect2, varscan2
- DDX5 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV99858304; called by muse, mutect2, varscan2
- DIP2B | c.2626C>T p.Q876* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99999458; called by muse, mutect2, varscan2
- DNAH2 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV99318596; called by muse, mutect2, varscan2
- DNAH7 | c.9121G>A p.E3041K | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753140811, COSV56774194; called by muse, mutect2
- DNAH8 | c.2900G>A p.R967K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.07); catalogued as COSV100547280; called by muse, mutect2, varscan2
- DNAH8 | c.4906G>A p.G1636R | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1042338640, COSV100547282; called by muse, mutect2, varscan2
- DOCK2 | c.5060G>A p.G1687E | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as rs1032678330, COSV99915657; called by muse, mutect2, varscan2
- DOK5 | c.409+1G>A p.X137_splice | Splice Site (SNP) | VAF 17/57 reads (30%) | catalogued as rs1568798425, COSV99374861; called by muse, mutect2, varscan2
- DSC1 | c.2425G>A p.G809R | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.955); catalogued as rs1358204708, COSV57151550; called by muse, mutect2, varscan2
- DUS3L | c.802G>T p.G268W | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV100288508; called by muse, mutect2, varscan2
- EBF2 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV68778055, COSV68778944; called by muse, mutect2, varscan2
- EGFL8 | c.235C>A p.R79S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as COSV100247112; called by muse, mutect2, varscan2
- ENPEP | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV99488176; called by muse, mutect2, varscan2
- EPHA2 | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1345084205, COSV100626309; called by muse, mutect2, varscan2
- ESCO2 | c.132A>T p.E44D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.321); catalogued as COSV100533425; called by muse, mutect2, varscan2
- FAAH2 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 70/305 reads (23%) | catalogued as rs1394464687, COSV66506732; called by muse, mutect2, varscan2
- FAM107B | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV99474475; called by muse, mutect2, varscan2
- FAM47A | c.562T>A p.C188S | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.088); catalogued as COSV100650103; called by muse, mutect2, varscan2
- FCER1A | c.439A>G p.K147E | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV100929315; called by muse, mutect2, varscan2
- FCSK | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs370681598; called by muse, mutect2, varscan2
- FGFR1 | c.1307C>T p.S436F (on ENST00000447712 / NM_023110.3; = p.S434F on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58331443; called by muse, mutect2, varscan2
- FHOD1 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1182744774, COSV99264542; called by muse, mutect2, varscan2
- FLG | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 98/533 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as rs539986712, COSV100910455; called by muse, mutect2, varscan2
- FLG | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 89/228 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV100911707; called by muse, mutect2, varscan2
- FMO1 | c.1215G>A p.M405I | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs868057676, COSV100707843; called by muse, mutect2, varscan2
- FRAS1 | c.9431A>T p.D3144V | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV99356010; called by muse, mutect2, varscan2
- FUBP1 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.981); catalogued as COSV99629647; called by muse, mutect2, varscan2
- FYB2 | c.2008G>A p.V670M | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1417100400, COSV100599811; called by muse, mutect2, varscan2
- FYB2 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.043); catalogued as COSV100599812; called by muse, mutect2, varscan2
- GABRD | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs1405824159, COSV101059578; called by muse, mutect2, varscan2
- GAP43 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs747821934, COSV100525667, COSV100525884; called by muse, mutect2, varscan2
- GNL3 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 28/116 reads (24%) | catalogued as rs1448612388, COSV101187282; called by muse, mutect2, varscan2
- GRIK4 | c.1725C>A p.S575R | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV101483805; called by muse, mutect2, varscan2
- GRM5 | c.3521A>C p.D1174A (on ENST00000305447 / NM_001143831.2; = p.D1142A on NM_000842.4) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.073); catalogued as rs779506168, COSV100554656; called by muse, mutect2, varscan2
- GRM5 | c.3520G>A p.D1174N (on ENST00000305447 / NM_001143831.2; = p.D1142N on NM_000842.4) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.48); PolyPhen possibly damaging (0.579); catalogued as rs1456395852, COSV100554658; called by muse, mutect2, varscan2
- GSTM2 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 50/295 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53984685; called by muse, mutect2, varscan2
- GTSF1L | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 22/100 reads (22%) | catalogued as COSV100883960; called by muse, mutect2, varscan2
- HBD | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs868329922, COSV53082476; called by muse, mutect2, varscan2
- HCN2 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV99242334; called by muse, mutect2, varscan2
- HEPH | c.3419G>A p.R1140Q (on ENST00000343002; = p.R873Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs757725630, COSV57972226; called by muse, mutect2, varscan2
- HIVEP3 | c.6238C>T p.P2080S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV99914071; called by muse, mutect2
- HTR3E | c.1102G>A p.E368K (on ENST00000415389 / NM_001256613.1; = p.E383K on NM_182589.2) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.047); catalogued as COSV58945796; called by muse, mutect2, varscan2
- IGHD | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); catalogued as COSV101163037; called by muse, mutect2, varscan2
- IGLV8-61 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 91/210 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs199887007, COSV101135160; called by muse, mutect2, varscan2
- IL1R1 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99292910; called by muse, mutect2, varscan2
- IMPG2 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99516593; called by muse, mutect2, varscan2
- IPO11 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV57583073; called by muse, mutect2, varscan2
- ITGA5 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99516979; called by muse, mutect2
- ITIH4 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99819913; called by muse, mutect2, varscan2
- IVL | c.1582G>A p.G528R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.589); catalogued as rs1187217536, COSV100908276; called by muse, mutect2
- IVL | c.1583G>A p.G528E | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as COSV100908190; called by muse, mutect2
- KAT6A | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs538688127, COSV99705929; called by muse, mutect2, varscan2
- KCNH8 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100111089; called by muse, mutect2, varscan2
- KDM8 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV99620045; called by muse, mutect2, varscan2
- KHDC4 | c.1791T>G p.Y597* | Nonsense Mutation (SNP) | VAF 37/175 reads (21%) | catalogued as COSV100851025, COSV64167152; called by muse, mutect2, varscan2
- KIAA1109 | c.7874C>T p.S2625F | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV99177248; called by muse, mutect2, varscan2
- KIFC1 | c.1499C>T p.T500I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1334784429, COSV101397087; called by muse, mutect2, varscan2
- KRTAP5-10 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 71/363 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.445); catalogued as COSV64794790; called by muse, mutect2, varscan2
- LAMA3 | c.9421C>T p.P3141S (on ENST00000313654 / NM_198129.4; = p.P1532S on NM_000227.6) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs267605133, COSV99335901; called by muse, mutect2, varscan2
- LAMB4 | c.3298C>T p.P1100S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs1266344817, COSV99225734; called by muse, mutect2, varscan2
- LCE3D | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.996); catalogued as COSV100909879; called by muse, mutect2, varscan2
- LPA | c.5597C>T p.S1866F | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV60306949; called by muse, mutect2, varscan2
- LRFN5 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as rs1051039315, COSV53243316, COSV53273551; called by muse, mutect2, varscan2
- LRP2 | c.9752T>A p.I3251N | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99790375; called by muse, mutect2, varscan2
- LRP2 | c.4126C>T p.P1376S | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99790376; called by muse, mutect2, varscan2
- LRRN2 | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100912979; called by muse, mutect2, varscan2
- MAGEA11 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as rs782156874, COSV60758474; called by muse, mutect2, varscan2
- MCPH1 | c.1130C>A p.T377N | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100766143; called by muse, mutect2, varscan2
- MED27 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV99406909; called by muse, mutect2, varscan2
- MEFV | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs1221398722, COSV99561290; called by muse, mutect2, varscan2
- MEFV | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1266566289, COSV99561336; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MFSD6L | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as rs772812130, COSV61004486; called by muse, mutect2, varscan2
- MMP28 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs267604816; called by muse, mutect2, varscan2
- MROH7 | c.39A>C p.E13D | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100274087; called by muse, mutect2, varscan2
- MROH7 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs990291011, COSV100274091; called by muse, mutect2, varscan2
- MRPS5 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 38/160 reads (24%) | catalogued as rs761781861, COSV55532824; called by muse, mutect2, varscan2
- MTUS2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1308572682, COSV70916329; called by muse, mutect2, varscan2
- MUC16 | c.22567A>G p.T7523A | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.136); catalogued as COSV101201828; called by muse, mutect2, varscan2
- MUC16 | c.5179G>A p.G1727R | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV101201829; called by muse, mutect2, varscan2
- MYH2 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99821020; called by muse, mutect2, varscan2
- MYL5 | c.112-1G>A p.X38_splice | Splice Site (SNP) | VAF 37/153 reads (24%) | catalogued as rs779883556, COSV100424741; called by muse, mutect2, varscan2
- MYL5 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs746798244, COSV100424742; called by muse, mutect2, varscan2
- MYO18B | c.4526G>A p.R1509K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV100125297; called by muse, mutect2, varscan2
- NAA15 | c.2269A>G p.R757G | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs1242438557, COSV99649949; called by muse, mutect2, varscan2
- NAALADL2 | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs770673045, COSV101495503; called by muse, mutect2, varscan2
- NCOR2 | c.5582C>T p.S1861F | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62299269; called by muse, mutect2, varscan2
- NELL1 | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.388); catalogued as COSV100125514; called by muse, mutect2, varscan2
- NELL2 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as COSV100420945; called by muse, mutect2, varscan2
- NGEF | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.712); catalogued as rs1436671055, COSV50922547; called by muse, mutect2, varscan2
- NLRP13 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.713); catalogued as COSV61622931; called by muse, mutect2, varscan2
- NLRP9 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV100243493; called by muse, mutect2, varscan2
- NR1H4 | c.350C>T p.P117L (on ENST00000551379 / NM_001206993.2; = p.P107L on NM_005123.4) | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV99501237; called by muse, mutect2, varscan2
- NUCKS1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 87/275 reads (32%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV65652881; called by muse, mutect2, varscan2
- NUDT8 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100039932; called by muse, mutect2, varscan2
- NUF2 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV99617041; called by muse, mutect2, varscan2
- NUMA1 | c.5829G>A p.R1943= | Splice Region (SNP) | VAF 18/72 reads (25%) | catalogued as COSV99475005; called by muse, mutect2, varscan2
- NYAP2 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as COSV56013260, COSV99798673; called by muse, mutect2, varscan2
- OR10G2 | c.462G>A p.W154* | Nonsense Mutation (SNP) | VAF 25/128 reads (20%) | catalogued as COSV101606972, COSV99075655; called by muse, mutect2, varscan2
- OR11H6 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs561839930, COSV100209980; called by muse, mutect2, varscan2
- OR2G2 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.568); catalogued as COSV100190015; called by muse, mutect2, varscan2
- OR2T33 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 100/276 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1287615696, COSV100532323; called by muse, mutect2, varscan2
- OR2T4 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 63/322 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539180269, COSV100822632; called by muse, mutect2, varscan2
- OR4D11 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs267603041, COSV100506645, COSV57586488; called by muse, mutect2, varscan2
- OR52E8 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV101191100; called by muse, mutect2, varscan2
- PCDHB1 | c.764G>A p.S255N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV100128428; called by mutect2, varscan2
- PCDHB3 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV50569134; called by muse, mutect2, varscan2
- PCDHGB6 | c.2191C>T p.L731F | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as COSV53897379, COSV99547551; called by muse, mutect2, varscan2
- PCLO | c.15274G>A p.G5092R | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100438217; called by muse, mutect2, varscan2
- PCLO | c.8852G>A p.R2951K | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.028); catalogued as rs1438102264, COSV100438222; called by muse, mutect2, varscan2
- PEG3 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 65/315 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs765630906, COSV55634529; called by muse, mutect2, varscan2
- PJVK | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100359811; called by muse, mutect2, varscan2
- PLG | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); catalogued as rs141045811, COSV51983039; called by muse, mutect2, varscan2
- PLXNA1 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1331182959, COSV99304172; called by muse, mutect2, varscan2
- PNP | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100829019; called by muse, mutect2, varscan2
- POLA1 | c.4097G>A p.R1366Q | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as rs769412757, COSV100985537; called by muse, mutect2, varscan2
- POTEE | c.2459C>T p.T820I | Missense Mutation (SNP) | VAF 52/349 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.95); catalogued as rs753743383, COSV100389058; called by muse, mutect2, varscan2
- PPP1R42 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | catalogued as rs763651966, COSV100221050; called by muse, mutect2, varscan2
- PPP3CB | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV55018753; called by muse, mutect2, varscan2
- PRDM8 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100325371; called by muse, varscan2
- PROX1 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.048); catalogued as COSV99800270; called by muse, mutect2, varscan2
- PRRG3 | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 67/328 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.933); catalogued as COSV64851465; called by muse, mutect2, varscan2
- PRSS1 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61194406; called by muse, varscan2
- PTEN | c.824_826dup p.V275_N276insI | In Frame Ins (INS) | VAF 6/35 reads (17%) | catalogued as CI092074; called by mutect2, pindel, varscan2
- PTPRD | c.5594G>A p.R1865K | Missense Mutation (SNP) | VAF 63/118 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV100647200, COSV61956862; called by muse, mutect2, varscan2
- RABGAP1L | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99274419; called by muse, mutect2, varscan2
- RAD9B | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100799452; called by muse, mutect2, varscan2
- REV3L | c.5555C>T p.P1852L | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1042805607, COSV100725700; called by muse, mutect2, varscan2
- RGS5 | c.282G>A p.W94* | Nonsense Mutation (SNP) | VAF 56/363 reads (15%) | catalogued as COSV100009203, COSV100009402; called by muse, mutect2, varscan2
- RHBDF2 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV100489688; called by muse, mutect2, varscan2
- RHBDL2 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100008703, COSV56709029; called by muse, mutect2, varscan2
- RNF152 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as COSV100455406, COSV57189176; called by muse, mutect2, varscan2
- RTL3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.106); catalogued as rs754233721, COSV100330118; called by muse, mutect2, varscan2
- RTL5 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.805); catalogued as COSV101030022, COSV101030367; called by muse, mutect2, varscan2
- RTN3 | c.851C>T p.S284F (on ENST00000377819 / NM_001265589.2; = p.S265F on NM_201428.3) | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV100380380; called by muse, mutect2, varscan2
- RYR1 | c.4417G>A p.V1473M | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100617096; called by muse, mutect2, varscan2
- RYR2 | c.6012G>A p.M2004I | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV100773094; called by muse, mutect2, varscan2
- SCAF8 | c.1508T>C p.I503T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100914289; called by muse, mutect2, varscan2
- SCAP | c.2962C>T p.R988W | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs148460850; called by mutect2, varscan2
- SCN11A | c.3629G>A p.G1210E | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as COSV100182641; called by muse, mutect2, varscan2
- SEC24D | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs142063505, COSV54881321; called by muse, mutect2, varscan2
- SEC63 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100938476; called by muse, mutect2, varscan2
- SEMA4C | c.2392G>T p.D798Y | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV100561187; called by muse, mutect2, varscan2
- SH3GL2 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.054); catalogued as COSV101014858; called by muse, mutect2, varscan2
- SIGLEC8 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201562965, COSV100367405; called by muse, mutect2, varscan2
- SLC25A26 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 73/284 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775283463, COSV99834470; called by muse, mutect2, varscan2
- SLC34A2 | c.2035C>A p.P679T | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV101158464; called by muse, mutect2, varscan2
- SLC34A2 | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.012); catalogued as COSV101158465; called by muse, mutect2, varscan2
- SLC5A12 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV101237764; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2182G>A p.D728N (on ENST00000540229 / NM_001371097.1; = p.D667N on NM_001009562.4) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV101045161; called by muse, mutect2, varscan2
- SMAP1 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV100391996; called by muse, mutect2, varscan2
- SMPD3 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1354866270, COSV99546088; called by mutect2, varscan2
- SNCAIP | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762552739, COSV54410850; called by muse, mutect2, varscan2
- SP140 | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.088); catalogued as COSV100614115; called by muse, mutect2, varscan2
- SP140 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as COSV100614117; called by muse, mutect2, varscan2
- SPATA20 | c.2050C>T p.P684S (on ENST00000356488 / NM_001258372.1; = p.P700S on NM_022827.4) | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV99136773; called by muse, mutect2, varscan2
- SPTBN4 | c.6955G>A p.G2319R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV100152197; called by muse, mutect2, varscan2
- SREBF1 | c.866C>T p.T289I | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV99889508; called by muse, varscan2
- TAL1 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1188161076, COSV53745987, COSV99595897; called by muse, mutect2, varscan2
- TBC1D20 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100830625; called by muse, mutect2, varscan2
- TBC1D20 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100830626, COSV62612826; called by muse, mutect2, varscan2
- TCAF2 | c.1061G>A p.G354D | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100633750; called by muse, mutect2, varscan2
- TCHHL1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1371250768, COSV100916620; called by muse, mutect2, varscan2
- TENM1 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 63/302 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as rs1403136982, COSV64434036; called by muse, mutect2, varscan2
- TIAM2 | c.4453G>A p.E1485K (on ENST00000529824; = p.E1456K on NM_012454.3) | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99266043; called by muse, mutect2, varscan2
- TMC4 | c.265C>T p.P89S (on ENST00000617472 / NM_001145303.3; = p.P83S on NM_144686.4) | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV99825084; called by muse, mutect2, varscan2
- TMX4 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as rs528800653, COSV99851662; called by muse, mutect2, varscan2
- TNRC18 | c.4606C>T p.P1536S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV101269886; called by muse, mutect2, varscan2
- TNXB | c.12905C>T p.P4302L (on ENST00000647633; = p.P4055L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100926679; called by muse, mutect2, varscan2
- TTN | c.21040C>T p.P7014S (on ENST00000591111; = p.P6087S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | PolyPhen benign (0.121); catalogued as COSV100631423; called by muse, mutect2, varscan2
- UGT1A1 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as rs762109713, COSV59392563, COSV59396677; called by muse, mutect2, varscan2
- UGT2B28 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs771912824, COSV100158498, COSV59434518; called by muse, mutect2, varscan2
- UPB1 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs367569283; called by muse, mutect2, varscan2
- USF3 | c.442A>T p.I148F | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100325831; called by muse, mutect2, varscan2
- USHBP1 | c.1654G>A p.G552R | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs753391965, COSV53102152, COSV99394567; called by muse, mutect2, varscan2
- VCX | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV100406407; called by muse, mutect2, varscan2
- VRK1 | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.218); catalogued as COSV99388668; called by muse, mutect2, varscan2
- WDR17 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99707169, COSV99708334; called by muse, mutect2, varscan2
- WDR33 | c.2398G>A p.G800R | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as COSV100460718; called by muse, mutect2, varscan2
- WRAP53 | c.1204T>G p.Y402D | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as COSV99873002; called by muse, mutect2, varscan2
- WSB1 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as COSV99286190; called by muse, mutect2, varscan2
- XDH | c.3351G>A p.W1117* | Nonsense Mutation (SNP) | VAF 52/240 reads (22%) | catalogued as COSV101052481; called by muse, mutect2, varscan2
- XKR3 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV100509392; called by muse, mutect2, varscan2
- XKR4 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59301129; called by muse, mutect2, varscan2
- XRCC4 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.953); catalogued as COSV99983416; called by muse, mutect2, varscan2
- ZAN | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 116/304 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as COSV100769795, COSV100770422; called by muse, mutect2, varscan2
- ZCCHC9 | c.116G>C p.R39P | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.052); catalogued as COSV54177637, COSV99562727; called by muse, mutect2, varscan2
- ZFPM2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV101023073; called by muse, mutect2, varscan2
- ZNF586 | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV101197750, COSV66972525; called by muse, mutect2, varscan2
- ZNF671 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.33); catalogued as COSV100235275; called by muse, mutect2, varscan2
- ZNF683 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV100853747; called by muse, mutect2, varscan2
- ZNF692 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs747549466, COSV100133951; called by muse, mutect2, varscan2
- ZP4 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63912021; called by muse, mutect2, varscan2
- ZSCAN29 | c.1867G>T p.E623* | Nonsense Mutation (SNP) | VAF 34/219 reads (16%) | catalogued as rs150098604, COSV101212248; called by muse, mutect2, varscan2
- ZXDA | c.956G>C p.R319T | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100699472; called by muse, mutect2, varscan2
- ZZEF1 | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as rs777140239, COSV101068107; called by muse, mutect2, varscan2
- EOLA2 | c.184G>T p.G62W | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR155 | c.1546dup p.Y516Lfs*37 | Frame Shift Ins (INS) | VAF 32/168 reads (19%) | called by pindel, varscan2
- GRK2 | c.442-6_443del p.X148_splice | Splice Site (DEL) | VAF 17/113 reads (15%) | called by mutect2, pindel, varscan2
- LRIG1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); called by muse, mutect2
- AHI1 | c.1329C>T p.V443= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs771792146, COSV99663812; called by muse, varscan2
- ARHGEF3 | c.819C>T p.I273= | Silent (SNP) | VAF 40/191 reads (21%) | catalogued as COSV99575982; called by muse, mutect2, varscan2
- ATP10B | c.3123G>A p.L1041= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV100515810; called by muse, mutect2, varscan2
- ATP12A | c.2319C>T p.I773= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as rs755436718, COSV54520790; called by muse, mutect2, varscan2
- BPTF | c.4719C>T p.I1573= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs757112658, COSV100076095, COSV100076101; called by muse, mutect2, varscan2
- CCDC137 | c.333C>A p.V111= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs769022420, COSV100235832; called by muse, mutect2, varscan2
- CCDC158 | c.1191G>A p.K397= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as rs545076452, COSV101187387; called by muse, mutect2, varscan2
- CCDC170 | c.402G>A p.Q134= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs555006174, COSV99498885; called by muse, mutect2, varscan2
- CEACAM16 | c.525C>T p.L175= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV101312763; called by muse, mutect2
- CHL1 | c.3060G>A p.G1020= (on ENST00000397491 / NM_001253387.1; = p.G1036= on NM_006614.4) | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs1417426947, COSV99852451; called by muse, mutect2, varscan2
- CLCN4 | c.2043C>T p.P681= | Silent (SNP) | VAF 56/296 reads (19%) | catalogued as rs770044114, COSV66464950, COSV66467094; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNOT7 | c.652C>T p.L218= | Silent (SNP) | VAF 51/216 reads (24%) | catalogued as COSV100778571; called by muse, mutect2, varscan2
- COL3A1 | c.4224C>T p.F1408= | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as rs549672243, COSV100483783; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL6A3 | c.984C>T p.F328= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs768609958, COSV55082487; ClinVar: likely benign; called by muse, mutect2, varscan2
- CROT | c.672C>T p.I224= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV100519699; called by muse, mutect2, varscan2
- CXCR1 | c.567G>A p.E189= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs1041985279, COSV99826442; called by muse, mutect2, varscan2
- CYP2C8 | c.657C>T p.F219= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100988032; called by muse, mutect2
- DDX5 | c.456C>T p.A152= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs782816392, COSV99858299; called by muse, mutect2, varscan2
- DLEC1 | c.1071C>T p.F357= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV57307544; called by muse, mutect2, varscan2
- DNAH7 | c.9123A>G p.E3041= | Silent (SNP) | VAF 26/148 reads (18%) | catalogued as rs1372290331, COSV100417727; called by muse, mutect2
- DNAH8 | c.2901G>A p.R967= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100547281; called by muse, mutect2, varscan2
- DNAJC22 | c.127C>T p.L43= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV101222610; called by muse, mutect2, varscan2
- DSC1 | c.2424G>A p.Q808= | Silent (SNP) | VAF 26/155 reads (17%) | catalogued as COSV99937368, COSV99938313; called by muse, mutect2, varscan2
- DSCAML1 | c.5544C>T p.S1848= (on ENST00000321322; = p.S1788= on NM_020693.4) | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2
- EMC3 | c.540G>A p.R180= | Silent (SNP) | VAF 48/172 reads (28%) | catalogued as COSV99794085; called by muse, mutect2, varscan2
- ENC1 | c.1263C>T p.I421= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as COSV100188262; called by muse, mutect2, varscan2
- ERAS | c.492C>T p.A164= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as rs781800923, COSV99504908; called by muse, mutect2, varscan2
- ERICH3 | c.2067G>A p.G689= | Silent (SNP) | VAF 77/284 reads (27%) | catalogued as rs1433150465, COSV58614053; called by muse, mutect2, varscan2
- FAM47A | c.561C>T p.F187= | Silent (SNP) | VAF 32/140 reads (23%) | catalogued as COSV100650104; called by muse, mutect2, varscan2
- FAM98A | c.504C>T p.F168= | Silent (SNP) | VAF 43/182 reads (24%) | catalogued as COSV99479568; called by muse, mutect2, varscan2
- FBXO40 | c.627G>A p.G209= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV100573328; called by muse, mutect2, varscan2
- FZD10 | c.1422C>T p.I474= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99969621; called by muse, mutect2, varscan2
- GCOM1 | c.894G>A p.R298= | Silent (SNP) | VAF 26/158 reads (16%) | catalogued as rs1407448838, COSV99985348; called by muse, mutect2, varscan2
- GJB5 | c.751C>T p.L251= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV100258711; called by muse, mutect2, varscan2
- GNL3 | c.393C>T p.C131= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as rs1377181338, COSV101187281; called by muse, mutect2, varscan2
- GPR174 | c.495G>A p.R165= | Silent (SNP) | VAF 35/173 reads (20%) | catalogued as COSV99338397; called by muse, mutect2
- GRIN2B | c.2328G>A p.V776= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV101663198; called by muse, mutect2, varscan2
- IGHV4-59 | c.243C>T p.S81= | Silent (SNP) | VAF 52/332 reads (16%) | called by muse, varscan2
- INKA2 | c.360C>T p.P120= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as rs1279592287, COSV100615886; called by muse, mutect2, varscan2
- IZUMO1 | c.186G>A p.K62= | Silent (SNP) | VAF 40/182 reads (22%) | catalogued as COSV99711125; called by muse, mutect2, varscan2
- KAT6A | c.1260C>T p.S420= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as COSV99705930; called by muse, mutect2, varscan2
- KCND3 | c.1203G>A p.V401= | Silent (SNP) | VAF 33/120 reads (28%) | catalogued as COSV100138499; called by muse, mutect2, varscan2
- KIF14 | c.1635C>T p.I545= | Silent (SNP) | VAF 60/133 reads (45%) | catalogued as rs1276356547, COSV100951096; called by muse, mutect2, varscan2
- LAMA2 | c.159G>A p.T53= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs1379023370, COSV101370868; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRC27 | c.465C>T p.L155= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as rs779244003, COSV100689978; called by muse, mutect2, varscan2
- MORC1 | c.2454G>A p.V818= | Silent (SNP) | VAF 30/144 reads (21%) | catalogued as COSV99227859; called by muse, mutect2, varscan2
- MRPS5 | c.540C>T p.D180= | Silent (SNP) | VAF 38/160 reads (24%) | catalogued as COSV99721074; called by muse, mutect2, varscan2
- MXRA5 | c.8448C>T p.L2816= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs774460007, COSV54223515; called by muse, mutect2, varscan2
- MYCBP2 | c.5733C>T p.L1911= (on ENST00000357337; = p.L1949= on NM_015057.5) | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as COSV100631998; called by muse, mutect2, varscan2
- MYH2 | c.2433G>A p.V811= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as rs760875686, COSV55448656; called by muse, mutect2, varscan2
- NEURL4 | c.2097G>A p.G699= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as COSV100223325; called by muse, mutect2, varscan2
- NLRP1 | c.3498C>T p.L1166= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs201587464, COSV99335567; called by muse, mutect2, varscan2
- NOSIP | c.486C>T p.F162= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100182493; called by muse, mutect2, varscan2
- NUCKS1 | c.714C>T p.A238= | Silent (SNP) | VAF 84/272 reads (31%) | catalogued as COSV100900810; called by muse, mutect2, varscan2
- NUF2 | c.1317G>A p.K439= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as COSV99617034; called by muse, mutect2, varscan2
- OR1D2 | c.42C>T p.L14= | Silent (SNP) | VAF 36/171 reads (21%) | catalogued as COSV100514005; called by muse, mutect2, varscan2
- OR2A12 | c.675G>A p.L225= | Silent (SNP) | VAF 180/461 reads (39%) | catalogued as COSV68821332; called by muse, mutect2, varscan2
- OR2G2 | c.597G>A p.E199= | Silent (SNP) | VAF 38/204 reads (19%) | catalogued as COSV100190011; called by muse, mutect2, varscan2
- OR2M4 | c.468G>A p.G156= | Silent (SNP) | VAF 74/209 reads (35%) | catalogued as COSV60709239; called by muse, mutect2, varscan2
- OR2T3 | c.138G>A p.G46= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as COSV100613299; called by muse, mutect2, varscan2
- OR2T34 | c.138G>A p.G46= | Silent (SNP) | VAF 40/211 reads (19%) | catalogued as COSV100170571; called by muse, mutect2, varscan2
- OR4K1 | c.270G>A p.K90= | Silent (SNP) | VAF 26/148 reads (18%) | catalogued as rs754389501, COSV99578649; called by muse, mutect2
- OR51F2 | c.705G>A p.E235= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as COSV59065340, COSV59066280; called by muse, mutect2, varscan2
- OR5M1 | c.255C>T p.F85= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as COSV73201948; called by muse, mutect2, varscan2
- OR7E24 | c.33C>T p.F11= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1173215882, COSV71702235; called by mutect2, varscan2
- OR9K2 | c.111C>T p.F37= (on ENST00000305377; = p.F15= on NM_001005243.1) | Silent (SNP) | VAF 43/176 reads (24%) | catalogued as COSV59531737, COSV59533264; called by muse, mutect2, varscan2
- PAGR1 | c.84C>T p.L28= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100232655, COSV100232811; called by muse, mutect2
- PCDHGA3 | c.1197T>C p.D399= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV99547548; called by muse, mutect2, varscan2
- PCLO | c.8853G>A p.R2951= | Silent (SNP) | VAF 69/210 reads (33%) | catalogued as COSV61673496; called by muse, mutect2, varscan2
- PDIA4 | c.450C>T p.D150= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV99618932; called by muse, mutect2, varscan2
- PELI1 | c.1083C>T p.T361= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as COSV100735190; called by muse, mutect2, varscan2
- PHF8 | c.2436G>A p.G812= (on ENST00000357988 / NM_001184896.1; = p.G776= on NM_015107.3) | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV100154913; called by muse, varscan2
- PPP1R42 | c.51C>T p.P17= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV100221483; called by muse, mutect2, varscan2
- PRPF6 | c.2580C>T p.A860= | Silent (SNP) | VAF 63/261 reads (24%) | catalogued as COSV99412885; called by muse, mutect2, varscan2
- PSMB11 | c.144C>T p.H48= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as rs765221013, COSV68430136; called by muse, mutect2, varscan2
- PVR | c.228C>T p.A76= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs1414992625, COSV99495990; called by muse, mutect2, varscan2
- PZP | c.1369C>T p.L457= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV99739586; called by muse, mutect2, varscan2
- RAB3D | c.603G>A p.G201= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs769851542, COSV55790816; called by muse, mutect2
- RAD54L | c.1938G>A p.V646= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs1275606756, COSV100586559; called by muse, mutect2, varscan2
- RBAK | c.1452C>T p.S484= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV100806784; called by muse, mutect2, varscan2
- RBM19 | c.1671C>T p.T557= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99926860; called by muse, mutect2, varscan2
- RICTOR | c.630C>T p.T210= | Silent (SNP) | VAF 48/237 reads (20%) | catalogued as COSV99705784; called by muse, mutect2, varscan2
- RSPO2 | c.186C>T p.F62= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as COSV52647965; called by muse, mutect2, varscan2
- RYR2 | c.819C>T p.S273= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs746461178, COSV100772837, COSV63693234; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN10A | c.4095C>T p.T1365= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs777516552, COSV71860452, COSV71861068; called by muse, mutect2, varscan2
- SCN5A | c.675G>A p.R225= | Silent (SNP) | VAF 2/16 reads (13%) | catalogued as COSV100350754; called by muse, mutect2
- SERPINA5 | c.273C>T p.I91= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100291531, COSV100291845; called by muse, mutect2, varscan2
- SGCZ | c.795C>T p.S265= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as COSV101171725, COSV66022045; called by muse, mutect2, varscan2
- SIPA1L3 | c.1686C>T p.S562= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as COSV55918079; called by muse, mutect2, varscan2
- SLC15A3 | c.654G>A p.A218= | Silent (SNP) | VAF 68/315 reads (22%) | catalogued as rs749670306, COSV99928852; called by muse, mutect2, varscan2
- SLC30A3 | c.933G>A p.S311= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs538009364, COSV99273777, COSV99273918; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC30A8 | c.60C>T p.F20= | Silent (SNP) | VAF 42/249 reads (17%) | catalogued as rs1031686258, COSV69970820; called by muse, mutect2, varscan2
- SMG9 | c.447C>T p.I149= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99526954; called by muse, mutect2, varscan2
- SREBF1 | c.867C>T p.T289= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as COSV99889506; called by muse, varscan2
- SSH1 | c.2961C>T p.F987= | Silent (SNP) | VAF 82/382 reads (21%) | catalogued as rs1346790352, COSV58459883; called by muse, mutect2, varscan2
- STK11 | c.558C>T p.T186= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs749563734, COSV100481083; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYS1 | c.462C>T p.S154= | Silent (SNP) | VAF 34/135 reads (25%) | catalogued as rs865906429, COSV99714007; called by muse, mutect2, varscan2
- TBX4 | c.681G>A p.V227= | Silent (SNP) | VAF 48/214 reads (22%) | catalogued as rs1298236240, COSV99540714; called by muse, mutect2, varscan2
- TDRKH | c.1554C>T p.A518= | Silent (SNP) | VAF 34/189 reads (18%) | catalogued as COSV100162713; called by muse, mutect2, varscan2
- TEX2 | c.2352C>T p.V784= (on ENST00000583097 / NM_001288733.2; = p.V791= on NM_018469.5) | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as COSV99367533; called by muse, mutect2, varscan2
- TM9SF1 | c.1522C>T p.L508= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as COSV99938311; called by muse, mutect2, varscan2
- TMC7 | c.1272C>T p.I424= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as COSV100432844; called by muse, mutect2, varscan2
- TMIGD2 | c.498C>T p.I166= | Silent (SNP) | VAF 119/543 reads (22%) | catalogued as rs376179994, COSV56667488; called by muse, mutect2, varscan2
- TNXB | c.12906C>T p.P4302= (on ENST00000647633; = p.P4055= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV100926678; called by muse, mutect2, varscan2
- TRPM2 | c.2343G>A p.V781= | Silent (SNP) | VAF 40/163 reads (25%) | catalogued as rs1161131613, COSV100309352; called by muse, mutect2, varscan2
- TSC1 | c.2022C>T p.V674= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs118203618, CD992771, COSV53765053; ClinVar: not provided / likely benign; called by muse, mutect2, varscan2
- TTN | c.22578G>A p.R7526= (on ENST00000591111; = p.R6599= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as COSV100631420; called by muse, mutect2, varscan2
- TUB | c.1068C>T p.S356= (on ENST00000299506 / NM_177972.3; = p.S411= on NM_003320.4) | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as COSV100210474; called by muse, mutect2, varscan2
- UMODL1 | c.3843C>T p.F1281= (on ENST00000408910 / NM_001004416.2; = p.F1409= on NM_173568.3) | Silent (SNP) | VAF 40/194 reads (21%) | catalogued as rs375378717; called by muse, mutect2, varscan2
- VEGFD | c.249C>T p.S83= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV52911185; called by muse, mutect2, varscan2
- VTCN1 | c.180T>A p.P60= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as COSV100062332; called by muse, mutect2, varscan2
- VWA8 | c.4398C>T p.I1466= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV101023005; called by muse, mutect2, varscan2
- WRAP53 | c.1203T>G p.G401= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV99872999; called by muse, mutect2, varscan2
- WSB1 | c.21G>A p.R7= | Silent (SNP) | VAF 27/217 reads (12%) | catalogued as COSV99286187; called by muse, mutect2, varscan2
- XDH | c.3882C>T p.L1294= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV101052480; called by muse, mutect2, varscan2
- ZFP57 | c.1185G>A p.K395= | Silent (SNP) | VAF 103/495 reads (21%) | catalogued as COSV100971971, COSV65306065; called by muse, mutect2, varscan2
- ZMAT1 | c.432C>T p.V144= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as COSV100858943; called by muse, mutect2, varscan2
- ZNF20 | c.792C>T p.F264= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as rs764313157, COSV100503176; called by muse, mutect2, varscan2
- ZNF391 | c.486G>A p.E162= | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as COSV99772833; called by muse, mutect2, varscan2
- ZNF423 | c.1602C>T p.F534= (on ENST00000563137 / NM_001379286.1; = p.F526= on NM_015069.4) | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV52175278; called by muse, mutect2, varscan2
- ZNF671 | c.879C>T p.A293= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as rs758477831, COSV100235271; called by muse, mutect2, varscan2
- ZP4 | c.1074C>T p.P358= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as COSV100850781; called by muse, mutect2, varscan2
- ZSCAN18 | c.1509C>T p.P503= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs760153250, COSV53731494; called by muse, varscan2
- C5orf64 | n.512+51989G>A | Intron (SNP) | VAF 30/143 reads (21%) | called by muse, mutect2, varscan2
- DCHS2 | n.7981G>A | RNA (SNP) | VAF 19/102 reads (19%) | catalogued as COSV100602709; called by muse, mutect2, varscan2
- DCHS2 | n.2788G>A | RNA (SNP) | VAF 14/69 reads (20%) | catalogued as COSV59718233; called by muse, mutect2, varscan2
- HERC2P3 | n.419C>T | RNA (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- KRTAP21-1 | c.*1A>T | 3'UTR (SNP) | VAF 45/209 reads (22%) | catalogued as rs767834843, COSV100624987; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640933 G>A | 3'Flank (SNP) | VAF 20/87 reads (23%) | catalogued as rs781617184, COSV51704549; called by muse, mutect2, varscan2
- MIR372 | n.7C>T | RNA (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- NACA | c.71-3650C>T | Intron (SNP) | VAF 26/107 reads (24%) | catalogued as COSV63269871; called by muse, mutect2, varscan2
- NEBL | c.164+46482G>A | Intron (SNP) | VAF 35/123 reads (28%) | catalogued as rs565525332, COSV65798567; called by muse, mutect2, varscan2
- PLCXD2 | c.*56C>T | 3'UTR (SNP) | VAF 16/142 reads (11%) | catalogued as rs748544895, COSV101208353; called by muse, mutect2, varscan2
- SV2C | c.581-20919C>T | Intron (SNP) | VAF 49/260 reads (19%) | catalogued as rs1185497397; called by muse, mutect2, varscan2
